Somatic mutation profile of tumor specimen TCGA-D8-A27V-01A (aliquot TCGA-D8-A27V-01A-12D-A17D-09) from TCGA case TCGA-D8-A27V, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 62.9 years (22,958 days).
Specimen TCGA-D8-A27V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 556a9bef-7a7f-45e2-9a81-70025f339e97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A27V-10A (Blood Derived Normal), aliquot TCGA-D8-A27V-10A-01D-A17D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2005d0c-923d-40ed-b589-a0d896f83b69

The open-access MAF lists 340 somatic variants for this specimen: 291 protein-altering or splice-affecting, 38 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Del 164, Missense Mutation 107, Silent 38, Nonsense Mutation 12, Intron 4, Splice Region 4, Splice Site 3, RNA 3, 3'UTR 2, Translation Start Site 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.2808del p.K936Nfs*24 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | catalogued as rs398122753; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CDH1 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | hotspot (GDC flag); catalogued as COSV55726950; called by muse, mutect2, varscan2
- ESR1 | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 32/100 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1057519827, COSV52782264; ClinVar: likely pathogenic; called by mutect2, varscan2
- TCF12 | c.842C>G p.S281* | Nonsense Mutation (SNP) | VAF 34/153 reads (22%) | catalogued as rs886037636, CD131550, CM131551, COSV51004208; ClinVar: pathogenic; called by mutect2, varscan2
- ABI3BP | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs1181708942, COSV52533017, COSV99425467, COSV99427035; called by muse, mutect2
- ACO2 | c.2179C>G p.Q727E | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV53441546; called by muse, mutect2, varscan2
- ACTL8 | c.1070G>C p.R357P | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs755110447, COSV64860446, COSV64862704; called by muse, varscan2
- AGAP1 | c.1911G>C p.L637F (on ENST00000304032 / NM_001037131.3; = p.L584F on NM_014914.5) | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58320205; called by mutect2, varscan2
- AGBL2 | c.2482del p.L828Wfs*8 | Frame Shift Del (DEL) | VAF 7/81 reads (9%) | catalogued as rs1310675921; called by mutect2, pindel
- AMBN | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); catalogued as rs200796492, COSV59825487; called by muse, mutect2, varscan2
- AMPD1 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV62415306; called by muse, mutect2, varscan2
- ANKRD12 | c.6018G>A p.M2006I | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV50820364; called by mutect2, varscan2
- ANKRD50 | c.3572C>G p.S1191C | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV72385258; called by muse, mutect2, varscan2
- ANPEP | c.969del p.I324Sfs*37 | Frame Shift Del (DEL) | VAF 7/80 reads (9%) | catalogued as COSV55594433; called by mutect2, pindel
- ANXA1 | c.37T>C p.F13L | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.162); catalogued as COSV57410644; called by mutect2, varscan2
- ATXN3 | c.138G>C p.M46I | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV100515412, COSV61494077; called by mutect2, varscan2
- B4GALNT2 | c.452A>G p.N151S | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV55925211; called by mutect2, varscan2
- BEND6 | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 43/122 reads (35%) | catalogued as COSV66068342; called by muse, mutect2, varscan2
- BRAF | c.1417G>A p.E473K (on ENST00000288602 / NM_001374244.1; = p.E433K on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.492); catalogued as COSV56102963; called by mutect2, varscan2
- BTAF1 | c.782C>A p.S261Y | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV56431009; called by muse, mutect2, varscan2
- BTNL9 | c.492C>G p.F164L | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV59794498; called by mutect2, varscan2
- CACNA1E | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.17); catalogued as rs1357407338, COSV62407225; called by mutect2, varscan2
- CACNA1E | c.2771G>A p.R924H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs764081616, COSV100701288, COSV100705611; called by muse, varscan2
- CACNG5 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV50054972; called by muse, varscan2
- CACTIN | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.021); catalogued as rs771249787, COSV99698284; called by muse, varscan2
- CARMIL1 | c.3006G>A p.A1002= | Splice Region (SNP) | VAF 11/34 reads (32%) | catalogued as rs368235973, COSV61518090; called by mutect2, varscan2
- CBX5 | c.303C>G p.I101M | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as COSV52935935; called by mutect2, varscan2
- CCDC136 | c.3250del p.D1084Tfs*53 | Frame Shift Del (DEL) | VAF 8/98 reads (8%) | catalogued as COSV52804880; called by mutect2, pindel
- CDCA2 | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as rs748745545, COSV55339171, COSV55339482; called by muse, mutect2, varscan2
- CDH24 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as rs756058912, COSV57459165; called by muse, mutect2, varscan2
- CDRT1 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV55410911; called by muse, varscan2
- CEP162 | c.2680G>A p.E894K | Missense Mutation (SNP) | VAF 66/176 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV57618189; called by mutect2, varscan2
- CERS1 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs555889038, COSV55928803; called by mutect2, varscan2
- CFAP97 | c.230del p.P77Qfs*5 | Frame Shift Del (DEL) | VAF 12/131 reads (9%) | catalogued as rs774713416; called by mutect2, pindel
- CLCN3 | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV61626497; called by mutect2, varscan2
- CNTNAP2 | c.3518del p.P1173Qfs*22 | Frame Shift Del (DEL) | VAF 5/54 reads (9%) | catalogued as COSV62226359; called by mutect2, pindel
- COG6 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.903); catalogued as COSV62995289; called by muse, varscan2
- CPA1 | c.516C>G p.I172M | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); catalogued as COSV50568359; called by muse, mutect2, varscan2
- DCTN4 | c.1264A>G p.K422E | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.187); catalogued as COSV101437531; called by mutect2, varscan2
- DDX3X | c.1318G>C p.D440H (on ENST00000399959; = p.D441H on NM_001356.5) | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as CD158037, COSV67863228; called by mutect2, varscan2
- DIS3L | c.2341G>A p.E781K (on ENST00000319212 / NM_001143688.3; = p.E698K on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.238); catalogued as COSV59911360; called by mutect2, varscan2
- DST | c.11713G>A p.E3905K (on ENST00000361203 / NM_001374722.1; = p.E1493K on NM_015548.5) | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.774); catalogued as COSV55002302; called by mutect2, varscan2
- DTL | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65341886; called by muse, mutect2, varscan2
- DYNC2H1 | c.12384G>C p.Q4128H | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.087); catalogued as COSV62088917; called by muse, mutect2, varscan2
- EIF2B4 | c.544C>T p.H182Y (on ENST00000347454 / NM_001034116.2; = p.H181Y on NM_015636.3) | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52006811; called by mutect2, varscan2
- EIF3A | c.1749G>C p.E583D | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV64960715; called by mutect2, varscan2
- EIF3B | c.2194G>C p.E732Q | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62802933; called by muse, mutect2, varscan2
- EIF4G3 | c.4270G>A p.E1424K | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as rs759286296, COSV51676361; called by mutect2, varscan2
- ELP1 | c.3059C>T p.S1020L | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV65896670; called by muse, varscan2
- EMILIN3 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs750502163, COSV60035396, COSV60037726; called by mutect2, varscan2
- ERICH6 | c.1150G>T p.V384L | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV55799297; called by mutect2, varscan2
- ETV3L | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1448150480, COSV71901000; called by mutect2, varscan2
- EVX1 | c.41del p.G14Vfs*35 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | catalogued as rs1438862348; called by mutect2, pindel
- FAM193A | c.3004G>A p.D1002N | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV61191906; called by mutect2, varscan2
- FAT3 | c.4853del p.P1618Rfs*3 | Frame Shift Del (DEL) | VAF 3/36 reads (8%) | catalogued as COSV53102741; called by mutect2, pindel
- FBN1 | c.7268G>A p.G2423E | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57311619; called by muse, mutect2, varscan2
- FBXO34 | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58253714; called by muse, varscan2
- FUBP3 | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV60513328; called by mutect2, varscan2
- FZD4 | c.887del p.G296Dfs*9 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | catalogued as COSV72294792; called by mutect2, pindel
- GARRE1 | c.1920del p.L640Ffs*10 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | catalogued as COSV55103271; called by mutect2, pindel
- GCLM | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 30/114 reads (26%) | catalogued as COSV64686787; called by mutect2, varscan2
- GPR156 | c.233+1del p.X78_splice | Splice Site (DEL) | VAF 3/25 reads (12%) | catalogued as COSV59942745; called by mutect2, pindel
- HCLS1 | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV58854884, COSV58855108; called by muse, mutect2, varscan2
- HCN1 | c.547G>C p.D183H | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57498086, COSV57525906; called by muse, mutect2, varscan2
- HELZ2 | c.7322del p.K2441Rfs*4 (on ENST00000467148 / NM_001037335.2; = p.K1872Rfs*4 on NM_033405.3) | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | catalogued as COSV64443147; called by mutect2, pindel
- HERC1 | c.11420C>G p.S3807* | Nonsense Mutation (SNP) | VAF 24/70 reads (34%) | catalogued as COSV71246606; called by mutect2, varscan2
- HGD | c.588del p.R197Gfs*32 | Frame Shift Del (DEL) | VAF 4/43 reads (9%) | catalogued as rs1257970701, CD002908, COSV99381149; called by mutect2, pindel
- HIVEP1 | c.1076C>G p.S359* | Nonsense Mutation (SNP) | VAF 34/72 reads (47%) | catalogued as COSV65099507; called by mutect2, varscan2
- HNRNPF | c.958G>C p.E320Q | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.301); catalogued as rs1345249865, COSV61560703; called by mutect2, varscan2
- HSPA12A | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 43/190 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.268); catalogued as COSV65021176; called by mutect2, varscan2
- IDI1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs929229161, COSV67281470; called by mutect2, varscan2
- IDS | c.147del p.S50Pfs*10 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | catalogued as CD094888; called by mutect2, pindel, varscan2
- ING1 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV58167227; called by muse, varscan2
- IREB2 | c.1864C>T p.R622C | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs898859127, COSV51921203, COSV51925705; called by mutect2, varscan2
- KCNJ15 | c.509G>C p.R170T | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV60810430; called by muse, mutect2, varscan2
- KDELR3 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.58); catalogued as COSV53246837; called by muse, mutect2, varscan2
- KLRK1 | c.348G>C p.E116D | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as COSV53698136; called by muse, mutect2, varscan2
- KMT2B | c.5043C>A p.F1681L | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV55858368; called by muse, mutect2, varscan2
- LCTL | c.1039C>T p.R347W | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs536892584, COSV57178734; called by mutect2, varscan2
- MACROD2 | c.195G>C p.K65N | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.787); catalogued as COSV53956838; called by muse, varscan2
- MANBA | c.2206C>G p.P736A (on ENST00000642252; = p.P690A on NM_005908.4) | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.519); catalogued as COSV56963593; called by muse, varscan2
- MAP1B | c.6534C>G p.I2178M | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.984); catalogued as COSV57095470; called by muse, mutect2, varscan2
- MCM4 | c.2473G>T p.E825* | Nonsense Mutation (SNP) | VAF 32/85 reads (38%) | catalogued as COSV50621124, COSV50621724; called by muse, mutect2, varscan2
- MEAF6 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV56162884; called by mutect2, varscan2
- MUC16 | c.12463G>C p.E4155Q | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as rs373360790; called by muse, mutect2, varscan2
- MYH15 | c.3139G>C p.E1047Q | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV56305778, COSV56310713, COSV99842969; called by mutect2, varscan2
- MYH15 | c.1141A>G p.R381G | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV56305796; called by mutect2, varscan2
- MYO16 | c.3181C>T p.Q1061* | Nonsense Mutation (SNP) | VAF 24/114 reads (21%) | catalogued as COSV62746747; called by mutect2, varscan2
- NAMPT | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55994478; called by muse, mutect2, varscan2
- NLRP10 | c.1185del p.D396Mfs*15 | Frame Shift Del (DEL) | VAF 5/51 reads (10%) | catalogued as COSV60782181; called by mutect2, pindel
- NLRP10 | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 19/80 reads (24%) | catalogued as COSV60779109; called by muse, mutect2, varscan2
- NUDT9 | c.345C>T p.I115= | Splice Region (SNP) | VAF 16/72 reads (22%) | catalogued as COSV56196149; called by mutect2, varscan2
- OR10J3 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as rs867791135, COSV59953822; called by muse, mutect2, varscan2
- OR13C3 | c.557C>G p.S186* | Nonsense Mutation (SNP) | VAF 18/76 reads (24%) | catalogued as COSV66165674; called by mutect2, varscan2
- OR13C8 | c.934T>C p.C312R | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV58610701; called by muse, mutect2, varscan2
- OR2T34 | c.801del p.S268Vfs*10 | Frame Shift Del (DEL) | VAF 8/108 reads (7%) | catalogued as COSV100170337; called by mutect2, pindel
- PAQR4 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); catalogued as rs369368361; called by muse, varscan2
- PCBP4 | c.776G>A p.R259H (on ENST00000322099 / NM_033010.2; = p.R216H on NM_020418.4) | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs753153356, COSV59053955; called by muse, mutect2, varscan2
- PDE4DIP | c.2801T>C p.L934P | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV57681956; called by mutect2, varscan2
- PDGFRB | c.760-1G>C p.X254_splice | Splice Site (SNP) | VAF 12/79 reads (15%) | catalogued as COSV55802238; called by muse, varscan2
- PHLDB2 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.214); catalogued as COSV67309008; called by muse, mutect2, varscan2
- PIGZ | c.457del p.A153Rfs*44 | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | catalogued as COSV53014166; called by mutect2, pindel
- PIP5K1B | c.648del p.E217Rfs*12 | Frame Shift Del (DEL) | VAF 5/54 reads (9%) | catalogued as COSV99599057; called by mutect2, pindel
- PKD1L1 | c.3588G>A p.M1196I | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV56960298; called by mutect2, varscan2
- PNPLA3 | c.634C>G p.L212V | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as rs1569011812, COSV53377536; called by mutect2, varscan2
- PRDM10 | c.1800del p.D601Ifs*3 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | catalogued as COSV58804495; called by mutect2, pindel
- PRDM2 | c.4279C>T p.Q1427* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as COSV52443908; called by muse, mutect2, varscan2
- PRKG2 | c.2196C>G p.L732= | Splice Region (SNP) | VAF 28/112 reads (25%) | catalogued as COSV100019319; called by mutect2, varscan2
- PRMT2 | c.457C>G p.L153V | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.592); catalogued as COSV52454509; called by mutect2, varscan2
- PTEN | c.1041C>A p.F347L | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV64292135; called by mutect2, varscan2
- RAB11FIP2 | c.244C>G p.L82V | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs745566329, COSV62924977; called by muse, mutect2, varscan2
- RAD18 | c.1393C>A p.L465I | Missense Mutation (SNP) | VAF 56/186 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.058); catalogued as COSV53749474, COSV53752214; called by mutect2, varscan2
- RGS12 | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs748051902, COSV60902774; called by muse, mutect2, varscan2
- ROCK2 | c.3011C>G p.S1004* | Nonsense Mutation (SNP) | VAF 22/80 reads (28%) | catalogued as COSV59954596; called by muse, mutect2, varscan2
- RYR2 | c.1633C>G p.R545G | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV63661399, COSV63698695, COSV63726168; called by mutect2, varscan2
- SARAF | c.677del p.P226Qfs*48 | Frame Shift Del (DEL) | VAF 8/92 reads (9%) | catalogued as COSV99822969; called by mutect2, pindel
- SASH1 | c.2467G>A p.E823K | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV66559620; called by muse, mutect2, varscan2
- SCN2A | c.5058G>C p.K1686N | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV51835052; called by mutect2, varscan2
- SDC2 | c.89T>C p.M30T | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as rs370731563, COSV56226420; called by muse, varscan2
- SEL1L | c.615-1G>T p.X205_splice | Splice Site (SNP) | VAF 38/141 reads (27%) | catalogued as COSV60919527; called by mutect2, varscan2
- SLC1A7 | c.1305del p.S436Pfs*25 | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | catalogued as COSV104396800; called by mutect2, pindel
- SLC37A3 | c.537del p.F179Lfs*18 | Frame Shift Del (DEL) | VAF 8/94 reads (9%) | catalogued as rs887174987; called by mutect2, pindel
- SLFN5 | c.1193C>T p.S398L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs760275920, COSV55480066; called by muse, mutect2, varscan2
- SMPD4 | c.1966G>A p.E656K (on ENST00000409031 / NM_017951.4; = p.E627K on NM_017751.4) | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.638); catalogued as COSV60078937; called by muse, mutect2, varscan2
- SNCAIP | c.1949G>C p.R650T | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as COSV54404475; called by muse, varscan2
- SRGAP3 | c.2209C>T p.P737S | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs771570436, COSV64531317; called by mutect2, varscan2
- SSR2 | c.309C>G p.F103L | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.519); catalogued as COSV55303312, COSV99828610; called by mutect2, varscan2
- STPG2 | c.482del p.G161Dfs*5 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | catalogued as COSV54796415; called by mutect2, pindel
- SULT4A1 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV50780489; called by mutect2, varscan2
- TBL1XR1 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.824); catalogued as COSV61789720; called by muse, mutect2, varscan2
- TENM4 | c.7159del p.E2387Rfs*14 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | catalogued as COSV53630425; called by mutect2, pindel
- TFEC | c.245C>G p.S82C | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.338); catalogued as COSV55398415; called by muse, mutect2, varscan2
- TFRC | c.145G>T p.D49Y | Missense Mutation (SNP) | VAF 56/224 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV64054083; called by mutect2, varscan2
- TMEM179B | c.105C>G p.F35L | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53667492; called by muse, mutect2, varscan2
- TMEM68 | c.684del p.V229Cfs*44 (on ENST00000434581 / NM_001363177.1; = p.V229* on NM_152417.3) | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | catalogued as COSV100588229; called by mutect2, pindel
- TNRC6B | c.4903+1del | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | catalogued as COSV100108996; called by mutect2, pindel
- TRPA1 | c.1513G>A p.G505S | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51557128; called by mutect2, varscan2
- TRPM6 | c.5176C>A p.P1726T | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV62504674, COSV62511090; called by mutect2, varscan2
- TTN | c.29395G>A p.E9799K (on ENST00000591111; = p.E8872K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/172 reads (26%) | PolyPhen probably damaging (0.994); catalogued as COSV59932837; called by mutect2, varscan2
- USP34 | c.5742G>A p.M1914I | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV68399346; called by muse, mutect2, varscan2
- UTP25 | c.879C>G p.F293L | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV71965774; called by mutect2, varscan2
- UTP3 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV54660768; called by muse, mutect2, varscan2
- XYLT1 | c.2260C>T p.R754C | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374020411, COSV54479975; called by muse, varscan2
- ZC3H6 | c.3364G>A p.G1122S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100674799, COSV59666487; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.357); catalogued as COSV60155930; called by muse, mutect2, varscan2
- ZMYND10 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.349); catalogued as COSV51600597; called by muse, mutect2, varscan2
- ZNF114 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs762508022, COSV59943767; called by muse, varscan2
- ZNF254 | c.1592C>T p.S531L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV61641146; called by muse, mutect2, varscan2
- ZNF429 | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as COSV61914961; called by muse, mutect2, varscan2
- ZNF536 | c.3256G>C p.E1086Q | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.422); catalogued as COSV62817906, COSV62820306; called by mutect2, varscan2
- ZNF85 | c.512del p.K171Rfs*15 | Frame Shift Del (DEL) | VAF 4/49 reads (8%) | catalogued as rs1568556649; called by mutect2, pindel
- ABI3BP | c.1828del p.S610Pfs*34 | Frame Shift Del (DEL) | VAF 6/72 reads (8%) | called by mutect2, pindel
- ACTG2 | c.110del p.G37Afs*8 | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- AKR1A1 | c.945del p.H316Ifs*24 | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | called by mutect2, pindel
- ALG5 | c.719del p.L240Yfs*23 | Frame Shift Del (DEL) | VAF 4/45 reads (9%) | called by mutect2, pindel, varscan2
- ALKBH5 | c.985del p.A329Qfs*61 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- APOL4 | c.25del p.I9Sfs*44 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | called by mutect2, varscan2
- ARHGAP31 | c.1304del p.F435Sfs*50 | Frame Shift Del (DEL) | VAF 4/45 reads (9%) | called by mutect2, pindel
- ARHGEF17 | c.1316del p.P439Lfs*8 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- ARID5A | c.770del p.P257Hfs*11 | Frame Shift Del (DEL) | VAF 5/56 reads (9%) | called by mutect2, pindel
- ASXL3 | c.2984del p.S995Tfs*30 | Frame Shift Del (DEL) | VAF 3/36 reads (8%) | called by mutect2, pindel
- ATP2C2 | c.266del p.H89Lfs*26 | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- BARD1 | c.1515del p.H506Mfs*4 | Frame Shift Del (DEL) | VAF 8/90 reads (9%) | called by mutect2, pindel
- BCL7A | c.195del p.G66Afs*10 | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | called by pindel, varscan2
- BCL9L | c.472del p.D158Tfs*24 | Frame Shift Del (DEL) | VAF 8/92 reads (9%) | called by mutect2, pindel
- BMP3 | c.1419del p.*473Yfs*50 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- BTBD6 | c.1428del p.Q477Rfs*33 | Frame Shift Del (DEL) | VAF 5/58 reads (9%) | called by mutect2, pindel
- C19orf44 | c.698del p.N233Tfs*26 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by pindel, varscan2
- CA5A | c.392del p.F131Sfs*6 | Frame Shift Del (DEL) | VAF 6/63 reads (10%) | called by mutect2, pindel
- CAD | c.5408del p.P1803Rfs*28 | Frame Shift Del (DEL) | VAF 4/45 reads (9%) | called by mutect2, pindel
- CAPZA2 | c.263del p.L88Wfs*14 | Frame Shift Del (DEL) | VAF 8/86 reads (9%) | called by mutect2, varscan2
- CARD14 | c.2482del p.R828Gfs*14 | Frame Shift Del (DEL) | VAF 4/41 reads (10%) | called by mutect2, pindel
- CARMIL2 | c.873del p.M292* | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- CARMIL3 | c.2916del p.R972Sfs*61 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- CARMIL3 | c.3067del p.E1023Rfs*10 | Frame Shift Del (DEL) | VAF 3/35 reads (9%) | called by mutect2, pindel
- CCL17 | c.119del p.G40Efs*8 | Frame Shift Del (DEL) | VAF 4/45 reads (9%) | called by mutect2, pindel
- CDH1 | c.360del p.H121Tfs*94 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- CEP192 | c.2197del p.Q733Nfs*5 | Frame Shift Del (DEL) | VAF 5/56 reads (9%) | called by mutect2, pindel
- CHST4 | c.700del p.Q234Kfs*12 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- CLASP2 | c.1409del p.L470* | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- COL3A1 | c.4154del p.N1385Mfs*2 | Frame Shift Del (DEL) | VAF 7/79 reads (9%) | called by mutect2, pindel
- CPB1 | c.1242del p.E414Dfs*6 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- CYB5D2 | c.448del p.Q150Rfs*2 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- DAG1 | c.2390del p.P797Lfs*46 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- DDOST | c.988del p.L330* (on ENST00000415136; = p.L313* on NM_005216.5) | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- DHX57 | c.1376del p.P459Qfs*32 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- DLEC1 | c.4467del p.E1490Sfs*8 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- EIF3A | c.2944del p.A982Qfs*191 | Frame Shift Del (DEL) | VAF 9/100 reads (9%) | called by mutect2, pindel
- EOMES | c.1412del p.G471Afs*61 | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- EPC2 | c.1666del p.R556Efs*7 | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | called by pindel, varscan2
- EPHX4 | c.515del p.G172Afs*2 | Frame Shift Del (DEL) | VAF 11/95 reads (12%) | called by mutect2, pindel, varscan2
- EPM2AIP1 | c.1289del p.N430Ifs*2 | Frame Shift Del (DEL) | VAF 5/44 reads (11%) | called by pindel, varscan2
- FAM181A | c.565del p.Q189Rfs*4 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- FAT3 | c.13075del p.W4359Gfs*10 | Frame Shift Del (DEL) | VAF 3/29 reads (10%) | called by mutect2, pindel
- FLI1 | c.338del p.P113Lfs*5 | Frame Shift Del (DEL) | VAF 7/79 reads (9%) | called by mutect2, pindel
- FLNA | c.5314del p.A1772Pfs*14 (on ENST00000369850 / NM_001110556.2; = p.A1764Pfs*14 on NM_001456.3) | Frame Shift Del (DEL) | VAF 3/35 reads (9%) | called by mutect2, pindel
- FREM2 | c.3840del p.K1280Nfs*2 | Frame Shift Del (DEL) | VAF 3/30 reads (10%) | called by mutect2, pindel
- FTO | c.1275del p.L426Sfs*10 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by pindel, varscan2
- GNAS | c.1023del p.R342Efs*5 | Frame Shift Del (DEL) | VAF 3/35 reads (9%) | called by mutect2, pindel
- GPR171 | c.342del p.Q115Sfs*2 | Frame Shift Del (DEL) | VAF 4/41 reads (10%) | called by mutect2, pindel
- GRB2 | c.585del p.G196Efs*18 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | called by mutect2, pindel, varscan2
- GRN | c.1018del p.H340Tfs*21 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel
- ITSN1 | c.5154del p.F1718Lfs*31 | Frame Shift Del (DEL) | VAF 5/50 reads (10%) | called by pindel, varscan2
- KALRN | c.4623del p.C1542Afs*19 | Frame Shift Del (DEL) | VAF 6/57 reads (11%) | called by pindel, varscan2
- KCNK18 | c.41del p.P14Qfs*18 | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | called by mutect2, pindel
- KDM4C | c.1209del p.D404Tfs*17 | Frame Shift Del (DEL) | VAF 7/81 reads (9%) | called by mutect2, pindel
- KDR | c.1036del p.E346Sfs*17 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- KIAA1522 | c.500del p.P167Rfs*10 (on ENST00000373480 / NM_001198972.2; = p.P226Rfs*10 on NM_020888.3) | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | called by mutect2, pindel
- KIF19 | c.811del p.A271Pfs*17 | Frame Shift Del (DEL) | VAF 7/64 reads (11%) | called by mutect2, pindel
- KIF5C | c.1528del p.R510Gfs*6 | Frame Shift Del (DEL) | VAF 5/58 reads (9%) | called by mutect2, pindel
- KRT26 | c.1139del p.L380* | Frame Shift Del (DEL) | VAF 5/42 reads (12%) | called by mutect2, pindel, varscan2
- KRTAP10-9 | c.204del p.Q68Hfs*313 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by pindel, varscan2
- LIMD2 | c.315del p.F106Lfs*165 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | called by pindel, varscan2
- LNP1 | c.139del p.T47Pfs*97 | Frame Shift Del (DEL) | VAF 7/72 reads (10%) | called by mutect2, pindel, varscan2
- LZTS3 | c.518del p.H173Pfs*34 | Frame Shift Del (DEL) | VAF 5/44 reads (11%) | called by mutect2, pindel, varscan2
- MAPKBP1 | c.3750del p.T1251Pfs*84 (on ENST00000456763 / NM_001128608.2; = p.T1245Pfs*84 on NM_014994.3) | Frame Shift Del (DEL) | VAF 7/74 reads (9%) | called by mutect2, pindel, varscan2
- MCM6 | c.634del p.Q212Kfs*13 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- MEIOC | c.827del p.L276Rfs*5 | Frame Shift Del (DEL) | VAF 3/22 reads (14%) | called by mutect2, pindel
- MFSD8 | c.1352del p.G451Vfs*7 | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | called by mutect2, pindel
- MLKL | c.897del p.D300Tfs*10 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel, varscan2
- MMP7 | c.513del p.P172Qfs*33 | Frame Shift Del (DEL) | VAF 5/57 reads (9%) | called by mutect2, pindel
- MUC16 | c.36928del p.S12310Afs*13 | Frame Shift Del (DEL) | VAF 10/112 reads (9%) | called by mutect2, pindel
- MYH11 | c.5296-3del | Splice Region (DEL) | VAF 5/53 reads (9%) | called by mutect2, pindel
- MYO1H | c.635del p.N212Tfs*108 | Frame Shift Del (DEL) | VAF 5/59 reads (8%) | called by mutect2, pindel
- N4BP1 | c.1617del p.K539Nfs*8 | Frame Shift Del (DEL) | VAF 5/59 reads (8%) | called by mutect2, pindel
- NAALADL1 | c.1959del p.M654Cfs*6 | Frame Shift Del (DEL) | VAF 4/49 reads (8%) | called by mutect2, pindel
- NAP1L1 | c.134del p.N45Ifs*16 | Frame Shift Del (DEL) | VAF 5/59 reads (8%) | called by mutect2, pindel
- NCAM2 | c.309del p.E104Kfs*4 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- NDUFA12 | c.83del p.F28Sfs*11 | Frame Shift Del (DEL) | VAF 5/42 reads (12%) | called by pindel, varscan2
- NELFB | c.1419del p.L474Cfs*112 | Frame Shift Del (DEL) | VAF 9/82 reads (11%) | called by mutect2, pindel, varscan2
- OR51G1 | c.260del p.F87Sfs*52 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel
- OR5AU1 | c.285del p.F95Lfs*4 | Frame Shift Del (DEL) | VAF 5/56 reads (9%) | called by mutect2, pindel
- OSBP2 | c.1813del p.E605Rfs*20 | Frame Shift Del (DEL) | VAF 10/100 reads (10%) | called by pindel, varscan2
- OTOP3 | c.66del p.E23Kfs*30 | Frame Shift Del (DEL) | VAF 3/23 reads (13%) | called by mutect2, pindel
- PARPBP | c.1556del p.N519Ifs*33 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by pindel, varscan2
- PIWIL4 | c.2506del p.S836Afs*10 | Frame Shift Del (DEL) | VAF 5/52 reads (10%) | called by pindel, varscan2
- PLD1 | c.2111del p.T704Kfs*4 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- PLPPR2 | c.35del p.F12Sfs*18 | Frame Shift Del (DEL) | VAF 7/81 reads (9%) | called by mutect2, pindel
- POR | c.224del p.K75Rfs*2 | Frame Shift Del (DEL) | VAF 8/82 reads (10%) | called by mutect2, pindel
- PSME3 | c.677del p.N226Ifs*9 | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | called by mutect2, pindel, varscan2
- RARG | c.1333del p.Q445Rfs*6 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel
- RASL10B | c.180del p.P61Hfs*55 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by pindel, varscan2
- RBKS | c.539del p.P180Lfs*27 | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- RETN | c.187del p.C63Afs*72 | Frame Shift Del (DEL) | VAF 4/45 reads (9%) | called by mutect2, pindel
- REXO1 | c.2618del p.G873Afs*48 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | called by mutect2, pindel
- RNF10 | c.2228del p.P743Lfs*32 | Frame Shift Del (DEL) | VAF 5/50 reads (10%) | called by pindel, varscan2
- RPL15 | c.126del p.T43Pfs*50 | Frame Shift Del (DEL) | VAF 5/38 reads (13%) | called by mutect2, pindel
- RPTOR | c.1614del p.L539Sfs*3 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- RUSC2 | c.3487del p.L1163Wfs*67 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- RYR3 | c.9325del p.L3109* (on ENST00000389232; = p.L3110* on NM_001036.6) | Frame Shift Del (DEL) | VAF 6/69 reads (9%) | called by mutect2, varscan2
- SLC25A3 | c.593del p.N198Tfs*3 (on ENST00000228318 / NM_005888.3; = p.N197Tfs*3 on NM_002635.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by pindel, varscan2
- SLC38A3 | c.704del p.K235Sfs*25 | Frame Shift Del (DEL) | VAF 8/86 reads (9%) | called by mutect2, pindel
- SMARCAL1 | c.167del p.N56Ifs*10 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | called by pindel, varscan2
- SMG6 | c.2758del p.L920Sfs*24 | Frame Shift Del (DEL) | VAF 6/72 reads (8%) | called by mutect2, pindel
- SOCS5 | c.656del p.P219Lfs*8 | Frame Shift Del (DEL) | VAF 3/24 reads (13%) | called by mutect2, pindel
- SOX14 | c.62del p.G21Afs*22 | Frame Shift Del (DEL) | VAF 7/73 reads (10%) | called by mutect2, pindel
- SOX2 | c.148del p.V50Cfs*53 | Frame Shift Del (DEL) | VAF 3/30 reads (10%) | called by mutect2, pindel
- STK11IP | c.874del p.W292Gfs*34 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- STOX2 | c.565del p.R189Gfs*56 | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | called by mutect2, pindel
- STYXL2 | c.3137del p.P1046Qfs*48 | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- SYNM | c.1035del p.D346Tfs*90 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- TAF3 | c.1305del p.A436Lfs*86 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- TENM4 | c.7708del p.V2570Sfs*5 | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- TFR2 | c.2377del p.D793Mfs*31 | Frame Shift Del (DEL) | VAF 5/55 reads (9%) | called by mutect2, pindel
- THAP11 | c.671del p.P224Lfs*9 | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | called by mutect2, pindel
- TIAM1 | c.1930del p.S644Vfs*32 | Frame Shift Del (DEL) | VAF 5/52 reads (10%) | called by pindel, varscan2
- TMEM229B | c.385del p.L129Sfs*29 | Frame Shift Del (DEL) | VAF 7/75 reads (9%) | called by mutect2, pindel
- TNRC6C | c.1254del p.G419Afs*9 | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | called by mutect2, pindel
- TNS1 | c.2675del p.P892Lfs*94 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by pindel, varscan2
- TOGARAM2 | c.573del p.E192Rfs*16 | Frame Shift Del (DEL) | VAF 3/26 reads (12%) | called by mutect2, pindel
- TPCN2 | c.1743del p.F582Lfs*68 | Frame Shift Del (DEL) | VAF 19/225 reads (8%) | called by mutect2, pindel
- TPST2 | c.522del p.N175Tfs*6 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- TRA2B | c.658del p.D220Ifs*72 | Frame Shift Del (DEL) | VAF 8/88 reads (9%) | called by mutect2, pindel
- TRBV24-1 | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- TRGV3 | c.25del p.L9* | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- TRIM28 | c.482del p.P161Qfs*18 | Frame Shift Del (DEL) | VAF 8/79 reads (10%) | called by mutect2, pindel
- TRIM68 | c.1235del p.P412Qfs*28 | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- TRPM8 | c.373del p.D125Tfs*9 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- TUBGCP6 | c.3724del p.H1242Mfs*82 | Frame Shift Del (DEL) | VAF 3/30 reads (10%) | called by mutect2, pindel
- UGT1A9 | c.801del p.N268Tfs*2 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- UNC13D | c.498del p.E167Rfs*82 | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | called by mutect2, pindel
- USP48 | c.411del p.D138Ifs*83 | Frame Shift Del (DEL) | VAF 8/102 reads (8%) | called by mutect2, pindel
- VPS25 | c.475del p.E159Sfs*109 | Frame Shift Del (DEL) | VAF 8/73 reads (11%) | called by mutect2, pindel
- VSIG10 | c.508del p.L170* | Frame Shift Del (DEL) | VAF 6/80 reads (8%) | called by mutect2, pindel
- WAC | c.134del p.K45Rfs*147 | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | called by mutect2, pindel
- ZDHHC1 | c.1150del p.A384Lfs*15 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | called by mutect2, pindel
- ZMYM2 | c.3464del p.G1155Efs*21 | Frame Shift Del (DEL) | VAF 3/42 reads (7%) | called by mutect2, pindel*
- ZNF292 | c.7467del p.T2490Qfs*3 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- ZNF397 | c.47del p.P16Lfs*6 | Frame Shift Del (DEL) | VAF 3/36 reads (8%) | called by mutect2, pindel
- ZNF408 | c.968del p.P323Qfs*46 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- ZNF655 | c.1369del p.V457Sfs*23 | Frame Shift Del (DEL) | VAF 3/35 reads (9%) | called by mutect2, pindel
- ABCA13 | c.2094C>G p.L698= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs1282991832, COSV70026547; called by muse, mutect2, varscan2
- AP3D1 | c.3435G>A p.E1145= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as rs1280399155, COSV61425401; called by muse, varscan2
- APOL4 | c.24A>G p.K8= | Silent (SNP) | VAF 6/41 reads (15%) | called by mutect2, varscan2
- ASXL3 | c.3141G>A p.R1047= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs766640644, COSV52460295; called by muse, varscan2
- CCDC183 | c.654G>A p.T218= | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as rs368449403; called by mutect2, varscan2
- CCT3 | c.81C>T p.I27= | Silent (SNP) | VAF 23/242 reads (10%) | catalogued as COSV55287886; called by mutect2, varscan2
- CD58 | c.78C>T p.I26= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs754340222, COSV65665410; called by muse, mutect2, varscan2
- CHD4 | c.5574G>A p.V1858= (on ENST00000357008 / NM_001363606.2; = p.V1868= on NM_001273.5) | Silent (SNP) | VAF 30/122 reads (25%) | catalogued as rs887048991, COSV58896287; called by mutect2, varscan2
- COQ8A | c.1281C>T p.F427= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV100825555; called by muse, mutect2, varscan2
- DHPS | c.147C>T p.F49= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV52951591, COSV52951708, COSV52952106; called by muse, varscan2
- DOCK10 | c.5016G>A p.K1672= | Silent (SNP) | VAF 39/156 reads (25%) | catalogued as rs762369571, COSV51357217; called by mutect2, varscan2
- DOCK11 | c.2649C>T p.T883= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as rs766253271, COSV52235142; called by muse, varscan2
- FLYWCH1 | c.1803G>C p.L601= (on ENST00000253928 / NM_001308068.2; = p.L600= on NM_020912.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV54144074; called by muse, mutect2
- GALNT12 | c.795C>T p.F265= | Silent (SNP) | VAF 28/132 reads (21%) | catalogued as rs774616588, COSV66662288; called by mutect2, varscan2
- GEMIN6 | c.303G>A p.E101= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV56140157; called by muse, mutect2, varscan2
- GXYLT2 | c.1305C>A p.I435= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV67473640; called by mutect2, varscan2
- IGKV2-30 | c.45C>G p.V15= | Silent (SNP) | VAF 12/86 reads (14%) | called by mutect2, varscan2
- ITGAM | c.2820C>G p.L940= (on ENST00000648685 / NM_001145808.2; = p.L939= on NM_000632.4) | Silent (SNP) | VAF 32/148 reads (22%) | catalogued as COSV54934890; called by mutect2, varscan2
- JAKMIP2 | c.1506C>T p.I502= | Silent (SNP) | VAF 44/194 reads (23%) | catalogued as rs753141914, COSV54599408, COSV99508161; called by mutect2, varscan2
- KRTAP6-1 | c.81T>C p.Y27= | Silent (SNP) | VAF 59/216 reads (27%) | catalogued as COSV58167922; called by mutect2, varscan2
- LRRFIP2 | c.447C>G p.L149= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as COSV100368671, COSV60866609; called by mutect2, varscan2
- MYH1 | c.1698C>T p.F566= | Silent (SNP) | VAF 37/132 reads (28%) | catalogued as COSV56844989; called by mutect2, varscan2
- NAALADL2 | c.216G>A p.Q72= | Silent (SNP) | VAF 23/37 reads (62%) | catalogued as COSV70794527; called by muse, varscan2
- NAXE | c.823C>T p.L275= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV58039219; called by muse, mutect2
- NCF2 | c.1110C>T p.L370= | Silent (SNP) | VAF 22/126 reads (17%) | catalogued as rs775303126, COSV62314945; called by muse, varscan2
- NWD1 | c.2095C>T p.L699= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV60338814; called by muse, mutect2, varscan2
- OR2Y1 | c.852C>G p.L284= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV57136232; called by muse, mutect2, varscan2
- PKP1 | c.477C>G p.L159= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as COSV55820231; called by muse, mutect2, varscan2
- RFXANK | c.600G>A p.G200= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV57393268; called by mutect2, varscan2
- SDC1 | c.873G>A p.P291= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs763262288, COSV54339192; called by muse, varscan2
- SLC23A2 | c.1395C>T p.L465= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV57772136; called by muse, varscan2
- STIM1 | c.1939C>T p.L647= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as rs1297891038, COSV56152433; called by muse, varscan2
- TBC1D9B | c.2796G>C p.L932= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as COSV62281319; called by muse, mutect2, varscan2
- TBXT | c.870C>T p.Y290= | Silent (SNP) | VAF 44/94 reads (47%) | catalogued as COSV51616727; called by muse, mutect2, varscan2
- TNN | c.2301G>A p.L767= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV53422913; called by muse, mutect2, varscan2
- UCHL5 | c.294G>T p.L98= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as COSV100815277; called by mutect2, varscan2
- VCX3B | c.381G>A p.E127= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV66842440; called by muse, mutect2, varscan2
- ZNF681 | c.294G>A p.V98= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV68073757; called by muse, mutect2, varscan2
- ABHD17A | c.332+302del | Intron (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- CLN3 | c.222+644C>T | Intron (SNP) | VAF 31/160 reads (19%) | catalogued as rs775999656, COSV61105054; ClinVar: uncertain significance; called by mutect2, varscan2
- LARS2 | c.*677del | 3'UTR (DEL) | VAF 11/104 reads (11%) | called by mutect2, pindel, varscan2
- LINC01559 | n.300G>A | RNA (SNP) | VAF 34/114 reads (30%) | called by mutect2, varscan2
- MAF | c.*4230del | 3'UTR (DEL) | VAF 3/37 reads (8%) | called by mutect2, pindel
- MFRP | chr11:119346503 del A | 5'Flank (DEL) | VAF 7/80 reads (9%) | called by mutect2, pindel
- MIR30B | n.57G>A | RNA (SNP) | VAF 36/88 reads (41%) | called by mutect2, varscan2
- NBR2 | n.391del | RNA (DEL) | VAF 5/58 reads (9%) | called by mutect2, pindel
- NUDCD3 | c.509+17056del | Intron (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- RBM44 | c.-98-2171del | Intron (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- SWI5 | c.-96C>T | 5'UTR (SNP) | VAF 4/33 reads (12%) | catalogued as COSV60791472; called by muse, mutect2
